Surgical pathology report (de-identified scan), TCGA case TCGA-E1-5319, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Duke, specimen TCGA-E1-5319-01A (Primary Tumor).

[page 1 of 2]
Clinical History:

Not given.

Gross Examination:

A. "Brain tumor", received fresh for frozen section. A 1.9 x 0.5 x 0.4 cm fragment of pink-tan tissue is received. A representative section is frozen as AF1. Frozen section remnant is submitted in A1. The remainder of the tissue is submitted in a mesh a bag in A2.

B. "Brain Tumor (BF1)", received fresh for frozen section. A 6.5 x 5.0 x 2.0 cm aggregate of pink-tan tissue is received. A representative section is frozen as BF1. Frozen section remnant is submitted in B1. Representative sections of the remaining tissue are submitted in blocks B2 through B8. The remainder of the tissue is retained in formalin.

C. "Brain tumor", received fresh and placed in formalin. A 2.5 x 1.5 x 1.0 cm aggregate of pink-tan tissue is sectioned and submitted in blocks C1 through C2.

Intraoperative Consultation:

A. "Brain tumor": AF1 - glioma

B. "Brain tumor": BF1 - glioma/favor oligo

Microscopic Examination:

The specimen in container A labeled "brain tumor", container B labeled "brain tumor" and in container labeled C "brain tumor" consists of brain tissue but which is infiltrated and replaced by a population of neoplastic cells. In some areas the cells have round regular vesicular nuclei, clear cytoplasm and a fine vascular stroma. Focal calcifications and accumulation of cells around neurons and under the pia are prominent features. Necrosis and endothelial proliferation are not seen. Although astrocytic forms are seen in some areas, the cells are more likely to be reactive than neoplastic.

DIAGNOSIS:

A. "BRAIN TUMOR (AF1)":

WELL DIFFERENTIATED OLIGODENDROGLIOMA (WHO GRADE II)

Continued on next page...

Page: 1

Patient:

MRN:

Location:

FILE COPY

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Collection Date: [REDACTED]
Accession Date: [REDACTED]

Pathology Number: [REDACTED]

DIAGNOSIS:

B. "BRAIN TUMOR (BF1)":

WELL DIFFERENTIATED OLIGODENDROGLIOMA (WHO GRADE II) . .

C. "BRAIN TUMOR":

WELL DIFFERENTIATED OLIGODENDROGLIOMA (WHO GRADE II) .

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
Electronically signed: [REDACTED]

** END OF REPORT **

Patient: [REDACTED]
HX No: [REDACTED]
Location: [REDACTED]

DATE COPY

Source: NCI Genomic Data Commons file 1b30557a-103e-4d43-8731-170ac4603994 (TCGA-E1-5319.31D5346F-9F29-4EEE-86E4-BD01FAF9935D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).